Somatic mutation profile of tumor specimen 0DUHI6 from CCDI case PBCLEC, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Astrocytoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 10.1 years (3,678 days).
Specimen 0DUHI6: Tissue type: Tumor; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a38c97a3-e0af-4e70-9b88-3b7a681fd039.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DUHGA (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/44b01aa0-3d69-437c-82da-2388a4d81df4

The open-access MAF lists 3 somatic variants for this specimen: 2 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 2, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SSB | c.101A>G p.K34R | Missense Mutation (SNP) | VAF 127/473 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.124); catalogued as rs905545381; called by muse, mutect2, varscan2
- CPXM1 | c.2098C>G p.L700V | Missense Mutation (SNP) | VAF 13/407 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.807); called by muse, mutect2
- PRKD1 | c.2322T>C p.Y774= | Silent (SNP) | VAF 55/417 reads (13%) | called by muse, mutect2, varscan2
